TCGA case TCGA-FZ-5921 — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/345a375c-15cc-453a-8054-e68a35178082

Demographics
Sex at birth: female; Country of residence at enrollment: United States; Age at index: 85 years; Vital status: Dead; Days to death: 155 days; Cause of death source: Death Certificate.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 85.1 years (31,074 days); Year of diagnosis: 2007; Method of diagnosis: Cytology; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Pancreas Head.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 10.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 45 days; Days to treatment end: 112 days; Treatment dose: 20 Gy; Treatment outcome: Progressive Disease; Number of fractions: 5; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Whipple.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Recurrence of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Peritoneum, NOS. Age at diagnosis: 85.4 years (31,177 days); Days to diagnosis: 103 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 103 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Peritoneum, NOS; Days to recurrence: 103 days.
- Days to follow up: 155 days; Disease response: With Tumor.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FZ-5921-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.4; Intermediate dimension: 0.9; Shortest dimension: 0.4.
  Slide TCGA-FZ-5921-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30.
  Slide TCGA-FZ-5921-01A-01-BS1: Section location: Bottom; Percent tumor cells: 67; Percent tumor nuclei: 70; Percent normal cells: 3; Percent necrosis: 0; Percent stromal cells: 30.
- Sample TCGA-FZ-5921-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FZ-5921-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.7; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymph nodes examined: Yes; Tumor status: With tumor.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 155 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 155 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 103 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FZ-5921-01A-11D-1608-01): tumor purity 0.24, ploidy 1.99, whole-genome doublings 0.
